Somatic mutation profile of tumor specimen TCGA-34-5236-01A (aliquot TCGA-34-5236-01A-21D-1817-08) from TCGA case TCGA-34-5236, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 60.1 years (21,935 days).
Specimen TCGA-34-5236-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c404d06-fb60-4437-b26a-dcd331807b38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-5236-10A (Blood Derived Normal), aliquot TCGA-34-5236-10A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1663b801-4f99-4ceb-b8e1-343fc7ac79ee

The open-access MAF lists 219 somatic variants for this specimen: 160 protein-altering or splice-affecting, 51 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 51, Nonsense Mutation 7, Frame Shift Del 7, Splice Site 6, Intron 4, RNA 2, Frame Shift Ins 1, Splice Region 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.101G>C p.R34P | Missense Mutation (SNP) | VAF 18/69 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960096, COSV67960161, COSV67961129; called by muse, mutect2, varscan2
- TP53 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1057519996, COSV52666637, COSV52701687, COSV52759171; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA1 | c.1141G>T p.G381W | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66071726; called by muse, mutect2, varscan2
- ACSM1 | c.913-1G>C p.X305_splice | Splice Site (SNP) | VAF 15/60 reads (25%) | catalogued as COSV54641154; called by muse, mutect2, varscan2
- ACSM2A | c.415C>A p.Q139K (on ENST00000219054; = p.Q60K on NM_001308169.2) | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV54591047; called by muse, mutect2, varscan2
- ADAM20 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56456930; called by muse, mutect2, varscan2
- ADAMTS9 | c.822C>A p.D274E | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55792959; called by muse, mutect2, varscan2
- ANKS1B | c.1531C>G p.P511A | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1280161414, COSV61382336; called by muse, mutect2, varscan2
- APOBEC1 | c.169A>G p.N57D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV57550541; called by muse, mutect2, varscan2
- ASNS | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 91/195 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1288356442, COSV51556795; called by muse, mutect2, varscan2
- ASPM | c.4214G>T p.R1405L | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs143092798, COSV54141357; called by muse, mutect2, varscan2
- BNC2 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 21/262 reads (8%) | catalogued as COSV66159316; called by muse, mutect2
- BRDT | c.866T>C p.F289S | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV62868211; called by muse, mutect2, varscan2
- C11orf54 | c.173G>T p.R58I | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as COSV58681145, COSV58682681; called by muse, mutect2
- C19orf57 | c.280C>G p.P94A | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (1); PolyPhen possibly damaging (0.88); catalogued as rs780924564, COSV60970771; called by muse, mutect2, varscan2
- CASP4 | c.57A>T p.K19N | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV67744990; called by muse, mutect2, varscan2
- CCDC170 | c.2101A>G p.T701A | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV53347468; called by muse, mutect2, varscan2
- CD5L | c.95G>C p.R32P | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.317); catalogued as COSV63821903, COSV63823426; called by muse, mutect2, varscan2
- CDH12 | c.1963G>C p.D655H | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66399725, COSV66446847, COSV66457543; called by muse, mutect2, varscan2
- CEP152 | c.3345+1G>T p.X1115_splice | Splice Site (SNP) | VAF 14/134 reads (10%) | catalogued as COSV57866200; called by muse, mutect2
- CEP152 | c.3345G>T p.K1115N | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs1217181704, COSV57866214; called by muse, mutect2
- CEP97 | c.1700C>G p.A567G | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV59124706, COSV59128797; called by muse, mutect2
- CES4A | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV58658635; called by muse, mutect2, varscan2
- CHCHD3 | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.741); catalogued as COSV52785366; called by muse, mutect2, varscan2
- CHRNB3 | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51498458; called by muse, mutect2, varscan2
- CLSTN2 | c.2776G>T p.E926* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV71725809; called by mutect2, varscan2
- COL11A1 | c.3745G>C p.G1249R | Missense Mutation (SNP) | VAF 21/231 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV62196446, COSV62202109; called by muse, mutect2
- COL11A1 | c.2644C>G p.R882G | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100617476, COSV62173295, COSV62202117; called by muse, mutect2, varscan2
- COL24A1 | c.3556C>A p.P1186T | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65316389; called by muse, mutect2
- CPS1 | c.1937C>T p.T646I | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV51827773; called by muse, mutect2, varscan2
- CSMD3 | c.8138C>A p.S2713Y | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52214740; called by muse, mutect2, varscan2
- DIXDC1 | c.1663G>T p.E555* (on ENST00000440460 / NM_001037954.4; = p.E344* on NM_033425.4) | Nonsense Mutation (SNP) | VAF 11/102 reads (11%) | catalogued as COSV59463936; called by muse, mutect2, varscan2
- DLGAP1 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs763104989, COSV59807834; called by muse, mutect2, varscan2
- DMD | c.8487C>A p.S2829R | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.056); catalogued as COSV58960277; called by muse, mutect2, varscan2
- DMRT3 | c.715G>T p.V239F | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.844); catalogued as COSV51909274; called by muse, mutect2
- DNAH8 | c.7058G>T p.G2353V | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV59486861; called by muse, mutect2
- DSEL | c.3539A>G p.Y1180C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs779203835, COSV59495623; called by muse, mutect2, varscan2
- DSP | c.2429G>A p.G810E | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as rs1214751115, COSV65791838; called by muse, mutect2, varscan2
- DTNA | c.1138G>C p.A380P | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV52030895; called by muse, mutect2, varscan2
- ERN2 | c.191T>A p.L64Q | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.424); catalogued as COSV56838721; called by muse, mutect2, varscan2
- FAT3 | c.10716G>C p.K3572N | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); catalogued as COSV53188378; called by muse, mutect2
- FIG4 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs768175169, COSV57789330; called by muse, mutect2, varscan2
- GAB3 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs193262930, COSV100850674, COSV65821011; called by muse, mutect2, varscan2
- GALNT5 | c.2142G>C p.E714D | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as COSV52042175; called by muse, mutect2
- GPD2 | c.1278G>C p.E426D | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60098042; called by muse, mutect2
- HGS | c.2140C>T p.L714F | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV61268775, COSV61270851; called by muse, mutect2
- HRH1 | c.495G>T p.W165C | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67956179; called by muse, mutect2, varscan2
- INPP5A | c.894C>A p.N298K | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs569271876, COSV61254211; called by muse, mutect2, varscan2
- IQGAP3 | c.736G>C p.A246P | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV63255320; called by muse, mutect2, varscan2
- ITGA10 | c.403T>C p.S135P | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65199705; called by muse, mutect2, varscan2
- ITGAV | c.2333C>G p.S778W | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53720359; called by muse, mutect2
- KIF2C | c.1659T>G p.I553M | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV64765915; called by muse, mutect2, varscan2
- KLHL9 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.297); catalogued as COSV62922553; called by muse, mutect2
- L3MBTL3 | c.820G>T p.D274Y | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62390234; called by muse, mutect2, varscan2
- LRRC4C | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53440955; called by muse, mutect2, varscan2
- LRRC66 | c.805A>G p.I269V | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.259); catalogued as rs947729903, COSV58637390; called by muse, mutect2, varscan2
- LRRTM4 | c.902T>C p.I301T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.164); catalogued as COSV69143212; called by muse, mutect2, varscan2
- LTBP1 | c.3001G>T p.E1001* (on ENST00000404816 / NM_206943.4; = p.E675* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 14/103 reads (14%) | catalogued as COSV63199398; called by muse, mutect2, varscan2
- MAN2A2 | c.230A>T p.E77V | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as COSV64640268; called by muse, mutect2, varscan2
- MCAT | c.683C>G p.S228C | Missense Mutation (SNP) | VAF 20/245 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV51794042; called by muse, mutect2
- MDN1 | c.3406+2T>C p.X1136_splice | Splice Site (SNP) | VAF 14/135 reads (10%) | catalogued as COSV65525220; called by muse, mutect2
- MSH5 | c.953T>G p.L318R | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV65212074; called by muse, mutect2, varscan2
- MTMR11 | c.2086A>G p.I696V (on ENST00000439741 / NM_001145862.2; = p.I624V on NM_181873.3) | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as rs1553766774, COSV54967285; called by muse, mutect2, varscan2
- MUC16 | c.26593C>A p.P8865T | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV67470499, COSV67484173, COSV67502325; called by muse, mutect2
- MYH9 | c.518+1G>A p.X173_splice | Splice Site (SNP) | VAF 14/66 reads (21%) | catalogued as COSV53395080; called by muse, mutect2, varscan2
- MYO3A | c.1783G>T p.G595C | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs1386353726, COSV56353490; called by muse, mutect2, varscan2
- NAALADL2 | c.1096A>T p.S366C | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV69161005; called by muse, mutect2
- NCAM1 | c.1609G>T p.G537W (on ENST00000316851 / NM_181351.5; = p.G527W on NM_000615.7) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57514194; called by muse, mutect2, varscan2
- NCKAP1L | c.969G>T p.K323N | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53213690; called by muse, mutect2
- NCOA1 | c.2879T>C p.L960P | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56054817; called by muse, mutect2, varscan2
- NCOA5 | c.1589C>G p.S530C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV51648112; called by muse, mutect2, varscan2
- NEO1 | c.1576G>T p.A526S | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as COSV56079436; called by muse, mutect2, varscan2
- NLRP12 | c.1073G>A p.R358K | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60757252; called by muse, mutect2, varscan2
- NOTCH3 | c.6785C>G p.S2262C | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV54654383; called by muse, mutect2, varscan2
- NRXN1 | c.914G>T p.S305I | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV58502276; called by muse, mutect2, varscan2
- NWD1 | c.1139C>G p.S380* | Nonsense Mutation (SNP) | VAF 3/39 reads (8%) | catalogued as COSV60345281, COSV60353879; called by muse, mutect2
- ODC1 | c.1319C>A p.S440Y | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as COSV52173843; called by muse, mutect2
- OR1J1 | c.446G>C p.W149S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV52240183; called by muse, mutect2, varscan2
- OR2G3 | c.777C>A p.Y259* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | catalogued as COSV60683633; called by muse, mutect2, varscan2
- OR2M3 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 81/413 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV71759381; called by muse, mutect2, varscan2
- OR2T12 | c.954G>T p.R318S | Missense Mutation (SNP) | VAF 45/252 reads (18%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV58778477, COSV58780094; called by muse, mutect2, varscan2
- OR2T4 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 30/255 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.181); catalogued as COSV63543941; called by muse, mutect2, varscan2
- OR56B4 | c.827T>A p.I276N | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57205856; called by muse, mutect2
- OR5M8 | c.779G>A p.R260K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV59118560; called by muse, mutect2
- OR6C68 | c.490C>A p.L164I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs1156872021, COSV65564174; called by muse, mutect2, varscan2
- OR8U1 | c.813C>A p.D271E | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV100164007; called by muse, mutect2, varscan2
- PABPC3 | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV55807142; called by muse, varscan2
- PAX9 | c.496A>G p.I166V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.785); catalogued as COSV64062776; called by muse, mutect2, varscan2
- PDCD11 | c.3148C>T p.H1050Y | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.028); catalogued as COSV63935809; called by muse, mutect2, varscan2
- PIK3C3 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV100010043, COSV56286000; called by muse, mutect2
- PIKFYVE | c.5452G>T p.A1818S | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.977); catalogued as COSV52250663; called by muse, mutect2, varscan2
- PITPNB | c.219G>C p.R73S | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as COSV58063161; called by muse, mutect2, varscan2
- PKD2 | c.1621G>T p.D541Y | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV52942002; called by muse, mutect2, varscan2
- PLEKHA6 | c.1183G>T p.A395S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55331630, COSV55341478; called by muse, mutect2, varscan2
- PMS1 | c.1456G>C p.G486R | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.05); catalogued as COSV59721030; called by muse, mutect2, varscan2
- PPP1R3A | c.3110C>A p.S1037* | Nonsense Mutation (SNP) | VAF 82/263 reads (31%) | catalogued as COSV52889632, COSV52895053; called by muse, mutect2, varscan2
- PRG4 | c.2720C>A p.T907N | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV63355102; called by muse, mutect2, varscan2
- PRR16 | c.162G>A p.V54= (on ENST00000407149 / NM_001300783.2; = p.V31= on NM_016644.2) | Splice Region (SNP) | VAF 13/76 reads (17%) | catalogued as COSV65407773; called by muse, mutect2, varscan2
- PSG3 | c.785G>T p.C262F | Missense Mutation (SNP) | VAF 58/464 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59507295; called by muse, mutect2, varscan2
- PTPRA | c.583G>T p.G195C | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99400135; called by muse, mutect2
- PWP1 | c.1463G>C p.G488A | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.025); catalogued as COSV69833662; called by muse, mutect2, varscan2
- PZP | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV54372477; called by muse, mutect2
- RANBP17 | c.1802A>T p.Y601F | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV66658955; called by muse, mutect2, varscan2
- RASAL1 | c.1709G>T p.G570V | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55660595; called by muse, mutect2
- RBL1 | c.364A>G p.I122V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as rs1462413768, COSV60334712; called by muse, mutect2, varscan2
- RERG | c.551C>A p.T184K | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV57001046, COSV57006100; called by muse, mutect2, varscan2
- RNF144A | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV57983305; called by muse, mutect2, varscan2
- ROS1 | c.6275A>G p.Y2092C | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63862819; called by muse, mutect2
- SACS | c.9159G>T p.E3053D | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); catalogued as COSV66548236; called by muse, mutect2, varscan2
- SCAF11 | c.3275A>G p.Q1092R | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as rs1317103991, COSV65479637; called by muse, mutect2, varscan2
- SENP5 | c.1007A>T p.K336M | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV60211029; called by muse, mutect2, varscan2
- SFPQ | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV61759378; called by muse, mutect2
- SHROOM4 | c.2032A>G p.R678G | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs782743144, COSV56798855; called by muse, mutect2, varscan2
- SI | c.2048A>C p.K683T | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.179); catalogued as COSV52306232; called by muse, mutect2, varscan2
- SLC36A4 | c.739C>T p.L247F | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58398043; called by muse, mutect2
- SLITRK3 | c.1879C>A p.P627T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV53854611; called by muse, mutect2, varscan2
- SPTLC2 | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.513); catalogued as rs773212643, COSV53643888; called by muse, mutect2, varscan2
- SS18 | c.1198C>T p.P400S (on ENST00000415083 / NM_001007559.3; = p.P369S on NM_005637.3) | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); catalogued as COSV52264518; called by muse, mutect2
- SS18 | c.1197G>T p.Q399H (on ENST00000415083 / NM_001007559.3; = p.Q368H on NM_005637.3) | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.36); catalogued as COSV52264526; called by muse, mutect2
- SSTR3 | c.506T>A p.V169E | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.648); catalogued as COSV60730612; called by muse, mutect2, varscan2
- STRN | c.1380A>C p.R460S | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55753096; called by muse, mutect2, varscan2
- SVIL | c.2275G>T p.G759C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV63449490; called by muse, mutect2
- SYMPK | c.1243-2A>C p.X415_splice | Splice Site (SNP) | VAF 6/96 reads (6%) | catalogued as COSV55616868; called by muse, mutect2
- SYNE1 | c.21845G>T p.W7282L (on ENST00000367255 / NM_182961.4; = p.W7211L on NM_033071.3) | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54911444, COSV55131244; called by muse, mutect2
- TCF25 | c.1050G>C p.Q350H | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54534005; called by muse, mutect2, varscan2
- TCL1B | c.146C>A p.A49D | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.04); catalogued as COSV61552461; called by muse, mutect2
- TFDP1 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64743064; called by muse, mutect2, varscan2
- TNNI3 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as CM0910618, COSV52571562; called by muse, mutect2, varscan2
- TOP3A | c.1201G>T p.G401C | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765361178, COSV58181723; called by muse, mutect2, varscan2
- TPR | c.5057T>C p.M1686T | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV66606105; called by muse, mutect2
- TTN | c.44900C>A p.T14967N (on ENST00000591111; = p.T7543N on NM_003319.4) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | PolyPhen possibly damaging (0.663); catalogued as COSV60417438; called by muse, mutect2, varscan2
- TTN | c.16530G>C p.E5510D (on ENST00000591111; = p.E4583D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/366 reads (23%) | PolyPhen benign (0); catalogued as COSV100601631, COSV60417477; called by muse, mutect2, varscan2
- UHRF1 | c.704G>A p.R235Q (on ENST00000612630 / NM_001290050.1; = p.R248Q on NM_013282.4) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1186106912, COSV53577500; called by muse, mutect2
- USH2A | c.4814G>T p.G1605V | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56329910, COSV56356140, COSV56453580; called by muse, mutect2
- VIRMA | c.4641+1G>C p.X1547_splice | Splice Site (SNP) | VAF 30/196 reads (15%) | catalogued as COSV52592543; called by muse, varscan2
- VPS13A | c.1395A>T p.L465F | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV62441347; called by muse, mutect2, varscan2
- WDR47 | c.1661T>C p.F554S (on ENST00000369962 / NM_001142551.2; = p.F555S on NM_014969.5) | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV63060408; called by muse, mutect2
- ZFHX4 | c.2554G>T p.D852Y | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1184800062, COSV51502681; called by muse, mutect2, varscan2
- ZMYM4 | c.1471G>T p.G491C | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV58908493, COSV58919158; called by muse, mutect2, varscan2
- ZNF44 | c.1603T>A p.S535T (on ENST00000356109 / NM_001164276.2; = p.S487T on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.396); catalogued as COSV61136553; called by muse, mutect2
- ZNF460 | c.881A>T p.N294I | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.263); catalogued as COSV64416681; called by muse, mutect2, varscan2
- ZNF507 | c.523G>C p.V175L | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs574653667, COSV61333801; called by muse, mutect2, varscan2
- ZNF638 | c.1394A>G p.N465S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52499044; called by muse, mutect2, varscan2
- ZNF746 | c.1807A>G p.T603A | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as COSV61409156; called by muse, mutect2, varscan2
- ZNF780B | c.1546C>G p.L516V | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55468993; called by muse, mutect2, varscan2
- ZNF804B | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60862590; called by muse, mutect2, varscan2
- ZNF804B | c.3856C>A p.L1286M | Missense Mutation (SNP) | VAF 13/268 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV60817313, COSV60862601; called by muse, mutect2
- C6orf118 | c.1211del p.D404Vfs*30 | Frame Shift Del (DEL) | VAF 20/118 reads (17%) | called by mutect2, pindel, varscan2
- CD300LD | c.377C>A p.P126Q | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2
- CXorf66 | c.1028_1044del p.I343Rfs*8 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- ERBIN | c.3146del p.G1049Afs*21 | Frame Shift Del (DEL) | VAF 22/122 reads (18%) | called by mutect2, pindel, varscan2
- FGF20 | c.502del p.A168Hfs*41 | Frame Shift Del (DEL) | VAF 19/155 reads (12%) | called by mutect2, pindel, varscan2
- IGKV1-27 | c.259A>T p.S87C | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- IGKV3-15 | c.339C>G p.N113K | Missense Mutation (SNP) | VAF 21/228 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- IGKV6-21 | c.280A>G p.I94V | Missense Mutation (SNP) | VAF 46/282 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- IPO7 | c.2310_2311del p.E772Gfs*2 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- OBSCN | c.8344_8345insT p.R2782Lfs*22 | Frame Shift Ins (INS) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- POTEA | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- SH3RF2 | c.2017del p.A673Rfs*13 | Frame Shift Del (DEL) | VAF 23/98 reads (23%) | called by mutect2, pindel, varscan2
- TRMT6 | c.825_829del p.L275Ffs*10 | Frame Shift Del (DEL) | VAF 11/105 reads (10%) | called by mutect2, pindel, varscan2
- A2ML1 | c.1587C>T p.A529= | Silent (SNP) | VAF 12/176 reads (7%) | catalogued as rs1472187755, COSV55300292; called by muse, mutect2
- ACSM2A | c.414C>A p.I138= (on ENST00000219054; = p.I59= on NM_001308169.2) | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV54591035; called by muse, mutect2, varscan2
- ACTL6B | c.627G>A p.E209= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV50520262; called by muse, mutect2
- ACVR1C | c.678C>T p.S226= | Silent (SNP) | VAF 23/168 reads (14%) | catalogued as rs779024563, COSV54650873; called by muse, mutect2, varscan2
- BBX | c.210T>G p.T70= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as COSV57897036; called by muse, mutect2, varscan2
- C6orf118 | c.660T>C p.R220= | Silent (SNP) | VAF 6/105 reads (6%) | catalogued as COSV57820660; called by muse, mutect2
- DSCAM | c.5841G>A p.P1947= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs754261783, COSV68021904; called by muse, mutect2, varscan2
- EPHA6 | c.117G>T p.G39= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV67598246; called by muse, mutect2, varscan2
- FAM135A | c.270A>G p.K90= (on ENST00000370479 / NM_001351599.1; = p.K47= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV52060936; called by muse, mutect2
- FAM155A | c.454C>A p.R152= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV101030877, COSV65592289; called by muse, mutect2, varscan2
- GALK2 | c.933C>G p.L311= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV59106235; called by muse, mutect2, varscan2
- GALNT17 | c.1539T>G p.G513= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV61149872, COSV61198098; called by muse, mutect2
- GPR15 | c.1023C>G p.L341= | Silent (SNP) | VAF 18/143 reads (13%) | catalogued as COSV52521722; called by muse, mutect2, varscan2
- H2AC11 | c.162G>A p.A54= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs762950579, COSV60363036; called by muse, mutect2, varscan2
- HSPA4 | c.321G>A p.E107= | Silent (SNP) | VAF 29/120 reads (24%) | catalogued as COSV59183872; called by muse, mutect2, varscan2
- IRGC | c.541C>A p.R181= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV54986759, COSV99746674; called by muse, mutect2, varscan2
- KDM5A | c.4833A>C p.A1611= | Silent (SNP) | VAF 51/167 reads (31%) | catalogued as rs944373081, COSV66997022; called by muse, mutect2, varscan2
- MIP | c.681C>A p.L227= | Silent (SNP) | VAF 35/204 reads (17%) | catalogued as COSV57516169; called by muse, mutect2, varscan2
- MLST8 | c.186C>T p.Y62= | Silent (SNP) | VAF 9/201 reads (4%) | catalogued as COSV57031809; called by muse, mutect2
- MTUS2 | c.801G>A p.L267= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV70924704; called by muse, mutect2, varscan2
- MUC16 | c.30738C>T p.F10246= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV67488246; called by muse, mutect2, varscan2
- MYH8 | c.4993C>A p.R1665= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV101238483; called by muse, mutect2, varscan2
- MYO5A | c.3081G>T p.L1027= | Silent (SNP) | VAF 6/79 reads (8%) | catalogued as COSV62565969; called by muse, mutect2
- NCAM2 | c.1068C>A p.V356= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV53093936, COSV53109220; called by muse, mutect2, varscan2
- NLRP14 | c.1608G>A p.L536= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV55073160; called by muse, mutect2, varscan2
- NPHP3 | c.1008C>T p.F336= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs1327377543, COSV58131104; called by muse, mutect2, varscan2
- NRARP | c.324G>A p.K108= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV63083199; called by muse, mutect2
- OR5I1 | c.423C>A p.G141= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as COSV56889650; called by muse, mutect2, varscan2
- P2RY2 | c.741C>T p.I247= | Silent (SNP) | VAF 8/103 reads (8%) | catalogued as rs1286890743, COSV60778168; called by muse, mutect2
- PLCB1 | c.1914G>A p.G638= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs982327395, COSV62072294; called by muse, mutect2, varscan2
- RABGEF1 | c.1149C>T p.D383= (on ENST00000439720 / NM_001287061.2; = p.D370= on NM_014504.3 and 29 other RefSeq transcripts) | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as rs754496301, COSV53165861; called by muse, mutect2, varscan2
- RAE1 | c.702A>T p.G234= | Silent (SNP) | VAF 16/165 reads (10%) | catalogued as COSV64799181; called by muse, mutect2
- RAX | c.423G>T p.T141= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as COSV56875618; called by muse, mutect2, varscan2
- REG3A | c.21G>T p.L7= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV100532910, COSV59412536; called by muse, mutect2, varscan2
- RICTOR | c.1437C>T p.F479= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV57132402; called by muse, mutect2
- RIMKLB | c.825C>G p.V275= | Silent (SNP) | VAF 42/177 reads (24%) | catalogued as COSV55240677; called by muse, mutect2, varscan2
- RPA1 | c.1116A>G p.R372= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as COSV54614296; called by muse, mutect2, varscan2
- RSPRY1 | c.1464T>G p.S488= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV68028951; called by muse, mutect2, varscan2
- SCYL2 | c.1899G>A p.E633= | Silent (SNP) | VAF 5/93 reads (5%) | catalogued as COSV62571286; called by muse, mutect2
- SHC4 | c.306G>A p.L102= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV60118184; called by muse, mutect2, varscan2
- SPAG17 | c.6249C>G p.V2083= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV60470632; called by muse, mutect2, varscan2
- SYNGAP1 | c.1230C>T p.S410= | Silent (SNP) | VAF 25/221 reads (11%) | catalogued as COSV53387561; called by muse, mutect2, varscan2
- SYT16 | c.1377G>A p.L459= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV70860492; called by muse, mutect2, varscan2
- TCL1B | c.147C>A p.A49= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV61552464; called by muse, mutect2
- TNKS1BP1 | c.3882A>T p.A1294= | Silent (SNP) | VAF 17/144 reads (12%) | catalogued as COSV64103079; called by muse, mutect2, varscan2
- TNPO3 | c.960C>T p.D320= | Silent (SNP) | VAF 62/154 reads (40%) | catalogued as COSV55288385; called by muse, mutect2, varscan2
- TNXB | c.7983G>T p.L2661= (on ENST00000647633; = p.L2414= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as rs761150005, COSV100926434; called by muse, mutect2, varscan2
- TTN | c.63981C>A p.A21327= (on ENST00000591111; = p.A13903= on NM_003319.4) | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV60417395; called by muse, mutect2, varscan2
- ZNF714 | c.516T>G p.S172= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV52516421; called by muse, mutect2
- ZNF804A | c.1665C>A p.I555= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV56475963; called by muse, mutect2, varscan2
- ZSCAN31 | c.936A>T p.R312= | Silent (SNP) | VAF 35/211 reads (17%) | catalogued as COSV60181832; called by muse, mutect2, varscan2
- ABHD5 | c.774-656G>C | Intron (SNP) | VAF 25/109 reads (23%) | catalogued as COSV68904901; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81149865 G>T | 5'Flank (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- LDB3 | c.690-4657G>T | Intron (SNP) | VAF 23/85 reads (27%) | catalogued as COSV99555518; called by muse, mutect2, varscan2
- OR2U1P | n.857C>T | RNA (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- PRR14L | chr22:31676821 G>A | 3'Flank (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- RPL26P30 | n.612C>T | RNA (SNP) | VAF 32/228 reads (14%) | catalogued as rs1370515374; called by muse, mutect2, varscan2
- USH1C | c.1284+7696C>A | Intron (SNP) | VAF 4/34 reads (12%) | catalogued as rs766124113, COSV99140537; called by mutect2, varscan2
- ZNRF2 | c.469+4027G>T | Intron (SNP) | VAF 10/160 reads (6%) | catalogued as COSV59912507; called by muse, mutect2
